Gene-level copy-number profile of tumor specimen C3L-02348-02 from CPTAC case C3L-02348, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.3 years (21,302 days).
Specimen C3L-02348-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 57e4a937-9076-4b67-b20e-ad6384a6d956.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02348-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/3cc786de-eaa3-49f1-b8d8-e2a743cab9d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,290; copy number 2: 53,322; copy number 3: 3,789.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
